Somatic mutation profile of tumor specimen TCGA-L5-A8NM-01A (aliquot TCGA-L5-A8NM-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 84.7 years (30,936 days).
Specimen TCGA-L5-A8NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a2ba77c-9a05-4447-b6d9-bbba41eac655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NM-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NM-11A-12D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1190d2ce-592f-4389-9d18-317316852b95

The open-access MAF lists 1,746 somatic variants for this specimen: 1,326 protein-altering or splice-affecting, 374 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 873, Silent 374, Frame Shift Del 299, Frame Shift Ins 75, Nonsense Mutation 42, Intron 27, In Frame Del 13, Splice Site 11, Splice Region 11, 3'Flank 8, RNA 4, 3'UTR 3.

Variants (750 of 1,746; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCHE | c.1027dup p.T343Nfs*8 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | catalogued as rs754214624; ClinVar: likely pathogenic; called by mutect2, varscan2
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- DMD | c.3713del p.K1238Rfs*6 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs1557362198; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996dup p.Q666Pfs*47 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs770374710; ClinVar: pathogenic; called by mutect2, varscan2
- MAP3K13 | c.1506-1G>A p.X502_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); catalogued as COSV53983753; called by muse, mutect2, varscan2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- OBSL1 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as rs121918216, CM093471, COSV99216653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.2055dup p.A686Cfs*55 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs772595552; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RRM2B | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs863224191, COSV52567850; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- SLC12A1 | c.1163del p.F388Sfs*40 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | catalogued as rs779588655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA2 | c.1630C>T p.R544C (on ENST00000614293; = p.R514C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs199857912; called by muse, mutect2, varscan2
- ABCC11 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as rs148400454; called by muse, mutect2, varscan2
- ABCE1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs901361759, COSV56848861; called by muse, mutect2, varscan2
- ABCG8 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754133516, COSV55391570; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99587531; called by muse, mutect2, varscan2
- ABI3 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs751478175; called by muse, mutect2, varscan2
- AC092143.1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs751259620; called by mutect2, varscan2
- ACAD11 | c.216dup p.P73Tfs*8 | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | catalogued as rs1338918712; called by mutect2, pindel
- ACAD9 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs368227855; called by muse, mutect2, varscan2
- ACSL6 | c.836C>T p.T279M (on ENST00000379240; = p.T304M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763258364, COSV57300205; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 37/67 reads (55%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.1448G>A p.S483N (on ENST00000262607; = p.S242N on NM_177405.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762701854; called by muse, mutect2, varscan2
- ADAM2 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs746785098, COSV55864450; called by muse, mutect2, varscan2
- ADAMTS2 | c.669del p.P224Hfs*23 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | catalogued as rs748037345; called by mutect2, pindel, varscan2
- ADAMTS9 | c.5426G>A p.R1809Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150104451; called by mutect2, varscan2
- ADCY4 | c.1582del p.R528Gfs*3 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs746788867; called by mutect2, pindel, varscan2
- ADCY8 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs756126755; called by muse, varscan2
- ADD3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV53324836; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749355527, COSV66925104; called by muse, mutect2, varscan2
- ADGRB2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57076449; called by muse, mutect2, varscan2
- ADH1C | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753360532, COSV72463724; called by muse, mutect2, varscan2
- ADORA1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs770382721, COSV55141351; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1554870245; called by mutect2, pindel, varscan2
- AFF2 | c.3739G>A p.V1247I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs782105173, CM137536, COSV54011349; called by muse, mutect2
- AGXT | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as CM154497; called by muse, mutect2, varscan2
- AHNAK2 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs370578594; called by mutect2, varscan2
- AICDA | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV99984430; called by muse, mutect2, varscan2
- AICDA | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as rs775620434, COSV57565073; called by muse, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH16A1 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022445179; called by muse, mutect2
- ALDH1B1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs770591719, COSV66619291; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALMS1 | c.3686C>T p.T1229I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.729); catalogued as rs1460294405; called by muse, mutect2, varscan2
- AMBRA1 | c.1238G>T p.G413V (on ENST00000458649 / NM_001367468.1; = p.G323V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54050684; called by muse, mutect2, varscan2
- AMOTL1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV54414299; called by muse, mutect2, varscan2
- AMOTL1 | c.1103del p.P368Lfs*5 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV54417863; called by mutect2, pindel, varscan2
- ANK1 | c.2882C>T p.T961M | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs750168913; called by muse, mutect2, varscan2
- ANK2 | c.11848G>A p.E3950K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs746413508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.4817C>T p.T1606M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1415082553, COSV55085768; called by muse, mutect2
- ANKRD6 | c.1151del p.P384Hfs*21 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs1293318031; called by mutect2, pindel, varscan2
- ANKS1A | c.959dup p.P321Tfs*19 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs761903319; called by mutect2, varscan2
- AP1B1 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs368232828; called by muse, mutect2, varscan2
- AP4M1 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.135); catalogued as rs201065427, COSV57997352; called by muse, mutect2, varscan2
- ARHGAP33 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.362); catalogued as rs776243342, COSV50133365; called by mutect2, varscan2
- ARHGAP35 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780026082, COSV68333417; called by muse, mutect2, varscan2
- ARHGEF26 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs374617836; called by muse, mutect2, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as COSV61372766; called by mutect2, varscan2
- ARL10 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs140105577; called by muse, mutect2, varscan2
- ARL13B | c.1118C>T p.T373M (on ENST00000394222 / NM_001174150.2; = p.T266M on NM_144996.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.558); catalogued as rs369850890; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASCC2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs766086654, COSV57075413; called by mutect2, varscan2
- ASGR1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs777852498; called by muse, mutect2, varscan2
- ATG2A | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101034711; called by muse, mutect2, varscan2
- ATG2B | c.6082G>A p.V2028M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763842413; called by muse, mutect2, varscan2
- ATG7 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV61615019; called by muse, mutect2, varscan2
- ATOH7 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774558993; called by muse, mutect2, varscan2
- ATP2A1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs769076880; called by mutect2, varscan2
- ATP4A | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773568287, COSV52865825, COSV52872123; called by muse, mutect2, varscan2
- ATP7B | c.2165T>G p.L722R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM1510475; called by muse, mutect2, varscan2
- ATP8B3 | c.2023del p.A675Qfs*97 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs750175510; called by mutect2, pindel, varscan2
- ATR | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as rs757006178, COSV99052415; called by muse, mutect2, varscan2
- ATRNL1 | c.3876_3879del p.T1293Sfs*7 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs782171685; called by pindel, varscan2
- AVPR1A | c.1138A>C p.S380R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54548030; called by muse, mutect2, varscan2
- AZIN2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148628180; called by muse, mutect2, varscan2
- B3GAT1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs1165378998, COSV56995880; called by muse, mutect2, varscan2
- B9D2 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379434407; called by muse, mutect2, varscan2
- BANF2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs760131545; called by muse, mutect2, varscan2
- BAX | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs760733803, COSV53170903, COSV99509048; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs751794665; called by mutect2, varscan2*
- BIRC2 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs754662778, COSV57162758; called by muse, mutect2, varscan2
- BLVRA | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs200862503; called by muse, mutect2, varscan2
- BOD1L1 | c.6724C>T p.R2242* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as rs1350827648, COSV99238541; called by muse, mutect2, varscan2
- BOP1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs916181974; called by muse, mutect2, varscan2
- BRDT | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142308966, COSV62863712; called by muse, mutect2, varscan2
- C10orf90 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as rs752212319, COSV52958568; called by muse, mutect2, varscan2
- C1orf127 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs777328651; called by muse, mutect2, varscan2
- C9orf135 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65875502; called by muse, mutect2, varscan2
- CA14 | c.953_955del p.K318del | In Frame Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs782346389; called by pindel, varscan2
- CALCOCO1 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV100017443; called by muse, mutect2, varscan2
- CAMK2A | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.906); catalogued as rs1445974036, COSV62245965; called by muse, mutect2, varscan2
- CAPNS1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as rs771258476, COSV55822873; called by muse, mutect2, varscan2
- CATSPER1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752478488, COSV104393919; called by muse, mutect2, varscan2
- CATSPERE | c.1789dup p.Y597Lfs*40 | Frame Shift Ins (INS) | VAF 25/88 reads (28%) | catalogued as rs1558519658; called by mutect2, pindel, varscan2
- CBFA2T3 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as rs774579712, COSV51929833; called by muse, mutect2, varscan2
- CBLB | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs561530977; ClinVar: not provided; called by muse, mutect2, varscan2
- CBX6 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV53321453; called by mutect2, varscan2
- CCAR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs773478671; called by mutect2, varscan2
- CCDC112 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs745613153, COSV101100560; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCNF | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748943310; called by muse, mutect2, varscan2
- CCNL2 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as rs775974831, COSV68766177, COSV68766754; called by mutect2, varscan2
- CCR4 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs762113496, COSV58381447; called by muse, mutect2, varscan2
- CD93 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1385014959, COSV55666074; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 41/80 reads (51%) | catalogued as rs762805003; called by mutect2, varscan2
- CDC42BPG | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs778893381, COSV61347980; called by muse, mutect2, varscan2
- CDKN2A | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs587782797, CM1414339, COSV58697439, COSV58704986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPI | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367921628; called by muse, mutect2, varscan2
- CEP170B | c.3634A>G p.M1212V (on ENST00000453495; = p.M1141V on NM_015005.3) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs980595911; called by muse, mutect2, varscan2
- CEP76 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as rs766046312, COSV50867864; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs761800837; called by mutect2, varscan2
- CHAF1A | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as rs772551130; called by muse, mutect2, varscan2
- CHD3 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as rs1392580196; called by muse, mutect2, varscan2
- CHD4 | c.3145C>A p.L1049I (on ENST00000357008 / NM_001363606.2; = p.L1062I on NM_001273.5) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100537149; called by muse, mutect2
- CHIC1 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.13); catalogued as rs896458368; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA2 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343360611; called by muse, mutect2, varscan2
- CHRNE | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370019023, CM123188; called by muse, mutect2, varscan2
- CHRNE | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs771950733, COSV53419220; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CLCF1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104894203, CM066008, COSV100425603; called by muse, mutect2
- CLCN6 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs755624300; called by mutect2, varscan2
- CLEC16A | c.2954C>A p.P985H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55489154; called by muse, mutect2, varscan2
- CLGN | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57776306; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CMA1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs139700002; called by muse, mutect2, varscan2
- CNNM1 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs780567307; called by muse, mutect2, varscan2
- CNTNAP4 | c.2463del p.F821Lfs*11 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as COSV56681724; called by mutect2, pindel, varscan2
- CNTROB | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs749738236; called by muse, mutect2, varscan2
- COG6 | c.548dup p.K184Qfs*11 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | catalogued as rs781236436; called by mutect2, pindel, varscan2
- COL18A1 | c.4787G>A p.G1596D (on ENST00000359759 / NM_130444.3; = p.G1361D on NM_030582.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275027041; called by muse, mutect2
- COL22A1 | c.2653C>T p.Q885* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100276184; called by muse, varscan2
- COL26A1 | c.1009C>T p.R337* (on ENST00000313669 / NM_001278563.3; = p.R335* on NM_133457.4) | Nonsense Mutation (SNP) | VAF 18/127 reads (14%) | catalogued as rs926155167, COSV58127155; called by muse, mutect2, varscan2
- COX20 | c.149del p.L50Cfs*14 | Frame Shift Del (DEL) | VAF 13/132 reads (10%) | catalogued as rs1313693363; called by mutect2, pindel
- COX7A1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53085061; called by muse, mutect2, varscan2
- CPSF7 | c.644T>C p.V215A (on ENST00000394888 / NM_001136040.4; = p.V258A on NM_024811.4) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs1203357514; called by muse, mutect2, varscan2
- CRACD | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310361150; called by muse, mutect2, varscan2
- CREBBP | c.435del p.A146Lfs*6 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | catalogued as COSV99268709; called by mutect2, pindel, varscan2
- CROCC | c.4049G>A p.R1350Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as rs140278341; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTCFL | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757349885; called by muse, mutect2, varscan2
- CTNNA1 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs1294176302, COSV57069858; called by muse, mutect2, varscan2
- CWH43 | c.2022-2A>T p.X674_splice | Splice Site (SNP) | VAF 33/86 reads (38%) | catalogued as rs774307079, COSV56940232; called by muse, mutect2, varscan2
- CXXC5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs372142920; called by muse, mutect2, varscan2
- CYBA | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022849964; called by muse, mutect2, varscan2
- CYLD | c.2310del p.P771Lfs*5 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV100282260; called by mutect2, pindel
- CYP17A1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752164207; called by muse, mutect2, varscan2
- CYP2F1 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs769976329; called by muse, mutect2, varscan2
- CYP4F2 | c.256del p.Q86Rfs*53 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as COSV50002127; called by mutect2, pindel, varscan2
- DAPK1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375598719; called by muse, mutect2, varscan2
- DAZAP2 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs749549625; called by muse, mutect2, varscan2
- DCANP1 | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs1454121506; called by muse, mutect2, varscan2
- DCP1B | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs756294843; called by mutect2, varscan2
- DDN | c.1215G>T p.W405C | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV60292180, COSV60292313; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs766714372; called by mutect2, varscan2
- DEF6 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57355754; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs553532837; called by mutect2, varscan2
- DHODH | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.214); catalogued as rs778495792, COSV54661941; called by muse, mutect2, varscan2
- DHRS1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs747329375, COSV55383365; called by muse, mutect2, varscan2
- DHRS12 | c.517G>A p.V173I (on ENST00000444610 / NM_001377930.1; = p.V124I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs145669707; called by muse, mutect2, varscan2
- DHX35 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs552753338, COSV52668870, COSV52674145; called by muse, mutect2, varscan2
- DICER1 | c.3464C>T p.T1155M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.072); catalogued as rs766598800; called by muse, mutect2, varscan2
- DLK2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs888511039, COSV55092347; called by muse, mutect2, varscan2
- DLX3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs376543839, COSV71547300; called by muse, mutect2, varscan2
- DNA2 | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64430420; called by muse, varscan2
- DNM2 | c.2585G>A p.R862H (on ENST00000355667 / NM_001005360.3; = p.R858H on NM_004945.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs369312570, COSV53033064; called by mutect2, varscan2
- DOC2A | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1390800519, COSV58751910; called by muse, mutect2, varscan2
- DOCK2 | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561287880, CM155077, COSV56951347, COSV99916343; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.5075G>A p.G1692D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1448168824; called by muse, mutect2, varscan2
- DOP1B | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489989315; called by muse, mutect2, varscan2
- DSC3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757290041, COSV64571675; called by muse, mutect2, varscan2
- DSN1 | c.183del p.G63Efs*39 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs35111724, COSV101041127; called by mutect2, pindel, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs755197346; called by mutect2, varscan2
- DYRK1B | c.1267del p.L423Wfs*80 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as COSV59914053; called by mutect2, pindel, varscan2
- E2F2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs757615854; called by muse, mutect2, varscan2
- EBF1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768501688, COSV58175661; called by muse, mutect2, varscan2
- EDIL3 | c.864del p.I289* | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as COSV99676088; called by mutect2, pindel, varscan2
- EFCAB13 | c.1925T>C p.L642S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs555824646; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EGFLAM | c.3004G>A p.V1002M (on ENST00000354891 / NM_001205301.2; = p.V994M on NM_152403.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs372253494; called by muse, mutect2, varscan2
- EGFR | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.079); catalogued as COSV51864573; called by muse, mutect2, varscan2
- EHD2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs371409023; called by mutect2, varscan2
- EHMT1 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs565543981, COSV71777389; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2AK4 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1161134551, COSV55467484; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3K | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1276223085; called by muse, mutect2, varscan2
- ELAVL3 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs778868611; called by muse, mutect2, varscan2
- EML4 | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs756245593, COSV59295869; called by muse, mutect2, varscan2
- EML5 | c.2263A>G p.I755V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749901278; called by muse, mutect2, varscan2
- EPHA4 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.745); catalogued as rs745528063; called by mutect2, varscan2
- EPHA8 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99385353; called by muse, mutect2, varscan2
- EPHB1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67668746; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs756407271; called by mutect2, varscan2
- EPPK1 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs782226851; called by muse, mutect2, varscan2
- EPS8L2 | c.2137del p.E713Rfs*114 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1564981057; called by mutect2, pindel, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- EVC2 | c.2380del p.E794Rfs*13 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV100186376; called by mutect2, pindel
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs760182064; called by mutect2, varscan2
- FA2H | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs1251854904, CM132962; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs766589051; called by mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM135B | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52752592; called by muse, mutect2, varscan2
- FAM53B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs762555526, COSV55103368; called by mutect2, varscan2
- FAM83H | c.2578C>T p.H860Y | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367570466, COSV62027922; called by muse, mutect2
- FAT3 | c.12811C>T p.P4271S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs774569185; called by muse, mutect2, varscan2
- FBLL1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748839022, COSV100606150; called by muse, mutect2, varscan2
- FBLN2 | c.641del p.G214Vfs*60 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs1442883568; called by mutect2, pindel, varscan2
- FBN2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs753160272; called by mutect2, varscan2
- FBXO31 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61150306; called by muse, mutect2
- FCGBP | c.447del p.G150Afs*25 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs765680504; called by mutect2, pindel
- FGD6 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs149076340; called by muse, mutect2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FLT4 | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs369284915; called by muse, mutect2, varscan2
- FLT4 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV56114905; called by muse, varscan2
- FNBP1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1175557567, COSV63085035; called by muse, mutect2, varscan2
- FNDC1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1384956388, COSV51933311; called by muse, mutect2
- FNTB | c.358del p.Q120Rfs*2 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs1482427198; called by mutect2, pindel, varscan2
- FOXH1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1341550325, CM082691; called by muse, mutect2, varscan2
- FOXRED2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs758632702, COSV53400706; called by muse, mutect2, varscan2
- FPGT | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs767286522, COSV63841450; called by muse, mutect2, varscan2
- FRMPD1 | c.1501C>A p.L501I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100899694; called by muse, mutect2, varscan2
- FZD3 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs770707567; called by muse, mutect2, varscan2
- GAA | c.1857C>A p.S619R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM034955; called by muse, mutect2, varscan2
- GAB4 | c.153dup p.E52Rfs*22 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | catalogued as rs764879401; called by mutect2, pindel, varscan2
- GABRA2 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100734165, COSV100734905; called by muse, mutect2, varscan2
- GALNTL5 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV67181003; called by muse, mutect2
- GAREM1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs945240079; called by muse, mutect2, varscan2
- GATA3 | c.35G>A p.S12N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as CD112075; called by muse, varscan2
- GATM | c.139del p.R47Gfs*29 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV101188100; called by mutect2, pindel, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 31/120 reads (26%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP7 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1419414098; called by muse, mutect2, varscan2
- GCN1 | c.5749del p.R1917Afs*40 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as COSV56112221; called by mutect2, pindel, varscan2
- GIPC1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs370004452; called by muse, mutect2, varscan2
- GLCE | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285607225, COSV55948791; called by muse, mutect2, varscan2
- GLO1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs371576917; called by muse, mutect2, varscan2
- GOLGA4 | c.5429T>C p.L1810S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1252012481; called by muse, mutect2, varscan2
- GON4L | c.1843_1845del p.E615del | In Frame Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs767906834; called by pindel, varscan2
- GPR158 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs1411470528; called by muse, mutect2, varscan2
- GPR20 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.057); catalogued as COSV66684774; called by muse, mutect2
- GPX7 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1160854999; called by muse, mutect2, varscan2
- GPX7 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as rs747249822, COSV63652615; called by mutect2, varscan2
- GRB14 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs766876255; called by muse, mutect2, varscan2
- GREB1 | c.4321C>T p.R1441W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs372022602; called by mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs749536463, COSV104408622; called by mutect2, varscan2
- GSDMA | c.1265del p.P422Qfs*33 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as COSV99227869; called by mutect2, pindel, varscan2
- GSTA1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs776912908, COSV58015002; called by muse, mutect2
- GSX2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58842712; called by muse, mutect2, varscan2
- GUCY2C | c.1120del p.D374Mfs*22 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs746745578; called by mutect2, pindel, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as COSV54945907; called by mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | catalogued as CM105646; called by mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs748396956; called by mutect2, varscan2
- HCFC2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99983051; called by muse, mutect2, varscan2
- HELQ | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs781237364; called by muse, mutect2, varscan2
- HELZ2 | c.5962C>T p.R1988C (on ENST00000467148 / NM_001037335.2; = p.R1419C on NM_033405.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200554251, COSV71296029, COSV71297138; called by muse, mutect2, varscan2
- HJURP | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs1185447339; called by muse, mutect2, varscan2
- HLA-C | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs281860324; called by muse, mutect2
- HMGB3 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV57487457; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXC9 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV57716800; called by muse, mutect2, varscan2
- HPF1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV66422614; called by muse, mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HPX | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750845591, COSV56419790; called by muse, varscan2
- HS6ST2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104426291; called by muse, mutect2, varscan2
- HTR6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); catalogued as rs1264801972, COSV57032801; called by muse, mutect2
- ICE1 | c.6524G>A p.R2175H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749806965; called by muse, mutect2, varscan2
- IDI2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs745577300, COSV52987448; called by mutect2, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as COSV63641012; called by mutect2, varscan2
- IGSF9B | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763829457; called by muse, mutect2, varscan2
- IKZF1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.732); catalogued as rs1422790468, COSV58792925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL18R1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV52122719; called by muse, mutect2, varscan2
- IL6 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV51733644; called by muse, mutect2, varscan2
- INCENP | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs142399783; called by muse, mutect2, varscan2
- INO80E | c.396G>A p.S132= | Splice Region (SNP) | VAF 8/65 reads (12%) | catalogued as rs997379972; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 13/20 reads (65%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP5F | c.788dup p.Q264Sfs*8 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | catalogued as rs750419826; called by mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQGAP2 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs537445542, COSV57171445; called by muse, mutect2, varscan2
- IQGAP3 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs111494634; called by mutect2, varscan2
- IRF4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705482; called by mutect2, varscan2
- IRX4 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1007542822; called by mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITIH2 | c.741G>A p.A247= | Splice Region (SNP) | VAF 9/42 reads (21%) | catalogued as rs769730496, COSV64432783, COSV64434540; called by muse, mutect2, varscan2
- ITPK1 | c.366C>T p.D122= | Splice Region (SNP) | VAF 4/33 reads (12%) | catalogued as rs746629240; called by muse, mutect2, varscan2
- ITPR1 | c.6608G>A p.R2203Q (on ENST00000354582; = p.R2148Q on NM_002222.7) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs781761068, COSV56982734; called by muse, mutect2, varscan2
- IVL | c.128del p.P43Hfs*22 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as COSV64216943; called by mutect2, pindel, varscan2
- JAKMIP2 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1237993499; called by muse, mutect2, varscan2
- JARID2 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV59190181; called by muse, mutect2, varscan2
- JUP | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs782052422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNAB2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs139249498; ClinVar: uncertain significance; called by mutect2, varscan2
- KCNC1 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as rs200123434; called by muse, mutect2, varscan2
- KCNH3 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99235985; called by muse, mutect2, varscan2
- KCNN3 | c.1117T>C p.C373R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99678711; called by muse, mutect2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs753256170; called by mutect2, pindel, varscan2
- KEAP1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99407450, COSV99408053; called by muse, mutect2
- KIF14 | c.4421C>T p.S1474L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1171587667; called by muse, mutect2, varscan2
- KLF17 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs745641456, COSV64856278; called by mutect2, varscan2
- KLHL30 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs374030236; called by muse, mutect2, varscan2
- KLHL30 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs747062547, COSV59976001, COSV59978799; called by muse, mutect2, varscan2
- KLK4 | c.627del p.L211* | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs1410607661; called by mutect2, pindel, varscan2
- KMT2B | c.2226G>T p.Q742H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV99385863; called by muse, mutect2, varscan2
- KMT2D | c.13432C>T p.R4478W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs562043836, COSV56497566, COSV99983233; called by mutect2, varscan2
- KREMEN1 | c.197A>G p.Y66C (on ENST00000407188; = p.Y68C on NM_032045.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59914502; called by muse, mutect2, varscan2
- KRT1 | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs1415994629; called by mutect2, varscan2
- KRT6A | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760660499; called by muse, mutect2, varscan2
- KSR1 | c.1034C>T p.S345L (on ENST00000644974 / NM_001367810.1; = p.S208L on NM_014238.2) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs1377720150; called by muse, mutect2, varscan2
- KSR2 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs771225839; called by muse, mutect2, varscan2
- LAG3 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs768238314, COSV52568168; called by mutect2, varscan2
- LAMA1 | c.4877C>T p.T1626M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs201454996; called by muse, mutect2, varscan2
- LAMA5 | c.7570G>A p.A2524T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs376340588; called by muse, mutect2, varscan2
- LAMA5 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs201613863, COSV99441232; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCE1C | c.305del p.G102Afs*45 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs765643412; called by mutect2, pindel, varscan2
- LCMT1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.302); catalogued as rs1323217864; called by muse, mutect2
- LGR5 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs747564622; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs748571616; called by mutect2, varscan2
- LIMD1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs35343448; called by muse, mutect2, varscan2
- LIMK2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs751350349, COSV59181559; called by muse, varscan2
- LINGO1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs371235435, COSV62437568; called by mutect2, varscan2
- LLGL1 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs756557977; called by muse, mutect2, varscan2
- LMCD1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1179506722, COSV50089217; called by muse, mutect2, varscan2
- LMO7 | c.3614C>T p.P1205L (on ENST00000357063; = p.P886L on NM_005358.5) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs774048028, COSV58534387; called by mutect2, varscan2
- LOXL4 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99584167; called by muse, mutect2, varscan2
- LPIN3 | c.1409A>C p.N470T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs750971260, COSV64717485; called by muse, mutect2, varscan2
- LPIN3 | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs749989327; called by muse, mutect2, varscan2
- LRP11 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as rs751287514; called by muse, mutect2, varscan2
- LRP2 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs759066438; called by muse, mutect2
- LRP5 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs1234898008, CM053973, COSV53716312; called by muse, mutect2
- LRRC14 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52877556; called by muse, mutect2, varscan2
- LRRIQ1 | c.2318G>A p.C773Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs1366811001; called by muse, mutect2, varscan2
- LUZP1 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs767898208, COSV56500791; called by mutect2, varscan2
- LYL1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1281479458, COSV53400443; called by muse, mutect2, varscan2
- LZTR1 | c.1582C>A p.L528I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.228); catalogued as rs1331354829, COSV99302290; called by muse, mutect2, varscan2
- MACF1 | c.6443C>T p.P2148L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs367548192; called by muse, mutect2, varscan2
- MAGEE1 | c.1678C>A p.L560M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63909552; called by muse, mutect2, varscan2
- MAN2A2 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs199747893, COSV64637650; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 9/90 reads (10%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAPK9 | c.289del p.T97Lfs*2 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1478217248; called by mutect2, pindel, varscan2
- MAPKAPK5 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as rs371560016; called by muse, mutect2, varscan2
- MAPRE1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs758889318, COSV65032433; called by muse, mutect2, varscan2
- MARCHF6 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV56883952; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1383130845; called by mutect2, varscan2
- MAST3 | c.1652T>A p.V551E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53221464; called by muse, mutect2
- MATN4 | c.1535G>A p.R512H (on ENST00000372754; = p.R471H on NM_003833.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | PolyPhen probably damaging (0.976); catalogued as rs778280289, COSV61352191; called by muse, mutect2, varscan2
- MAU2 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs748054579; called by muse, mutect2, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs755716804, COSV56502366; called by mutect2, pindel, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs558765093; called by mutect2, varscan2
- MCC | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs780749536, COSV100202435; called by muse, mutect2, varscan2
- MCOLN1 | c.1222_1224del p.F408del | In Frame Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs797044817; called by pindel, varscan2
- ME2 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs755200974; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | catalogued as rs759225724; called by mutect2, varscan2
- MELTF | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs151109969; called by muse, mutect2, varscan2
- MGAT4B | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1024360336, COSV99482208; called by muse, mutect2, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs778939334; called by mutect2, pindel, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MIER2 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs765452913, COSV53394593; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MPP5 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1352763103, COSV99907363; called by muse, mutect2, varscan2
- MPPED1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530556930; called by muse, mutect2, varscan2
- MPV17L2 | c.493del p.Q165Nfs*10 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | catalogued as rs746591385; called by mutect2, pindel, varscan2
- MRGPRX3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); catalogued as rs747757094, COSV101283560; called by muse, mutect2, varscan2
- MROH2B | c.2071dup p.S691Ffs*32 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs1199010949; called by mutect2, pindel
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs748849454; called by mutect2, pindel, varscan2
- MROH7 | c.66del p.S23Pfs*7 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs746143056; called by mutect2, pindel, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSH6 | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs773185557; ClinVar: uncertain significance; called by muse, varscan2
- MSI1 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1270520592; called by muse, mutect2, varscan2
- MTA1 | c.1913dup p.S639Lfs*18 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs1555433939; called by mutect2, varscan2
- MTERF3 | c.635dup p.N212Kfs*7 | Frame Shift Ins (INS) | VAF 26/95 reads (27%) | catalogued as rs759886730; called by mutect2, pindel, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs767880823; called by mutect2, varscan2
- MTR | c.3478G>A p.V1160I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1159496738; called by mutect2, varscan2
- MUC5AC | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); catalogued as rs1357774544, COSV100650586; called by muse, mutect2
- MUTYH | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs373803765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs552578060; called by muse, mutect2, varscan2
- MYCBP2 | c.4013C>T p.A1338V (on ENST00000357337; = p.A1376V on NM_015057.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62036963; called by muse, mutect2, varscan2
- MYH11 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55546409; called by muse, mutect2, varscan2
- MYH3 | c.2176C>A p.L726M | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56869400; called by muse, mutect2
- MYH6 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780305056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL9 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs752683922; called by mutect2, varscan2
- MYO16 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs761000065, COSV99194363, COSV99194421; called by muse, mutect2, varscan2
- MYO3A | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs56403976, COSV56324596; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAB2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754395904; called by muse, mutect2, varscan2
- NADK | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182911931, COSV58277020; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1346393455; called by mutect2, varscan2
- NBAS | c.224dup p.L75Ffs*4 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | catalogued as rs771933634; called by mutect2, pindel, varscan2
- NBEA | c.7058A>G p.K2353R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as rs1316665586; called by mutect2, varscan2
- NBEAL2 | c.3169C>T p.R1057W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs778212837; called by muse, mutect2, varscan2
- NBPF1 | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs3872315; called by muse, mutect2, varscan2
- NCKAP1L | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218763304, COSV53203993; called by muse, mutect2, varscan2
- NDUFA7 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs553849517, COSV100035606, COSV56847725; called by muse, mutect2, varscan2
- NEIL1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752228554; called by muse, mutect2, varscan2
- NELFB | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs752643955, COSV58025294; called by muse, mutect2, varscan2
- NES | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1458091128, COSV63963169; called by mutect2, varscan2
- NFATC2 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs774669305; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIFK | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs377016579; called by muse, mutect2, varscan2
- NIPBL | c.2174del p.P725Qfs*69 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV56959792; called by mutect2, pindel, varscan2
- NOP56 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs766864927; called by muse, mutect2, varscan2
- NOP9 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs759856552, COSV99350647; called by muse, mutect2, varscan2
- NPAS3 | c.1676G>A p.R559H (on ENST00000356141 / NM_001164749.2; = p.R527H on NM_022123.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60827860; called by muse, mutect2, varscan2
- NUP210 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs766961777; called by muse, mutect2, varscan2
- NWD1 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as rs150409927; called by muse, mutect2, varscan2
- NXPE3 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs914301439; called by muse, mutect2, varscan2
- OLFML2A | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs368703899; called by muse, mutect2, varscan2
- OLIG3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760047026, COSV62988529; called by muse, mutect2, varscan2
- OR10H2 | c.64del p.H22Tfs*4 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as COSV59945967; called by mutect2, pindel, varscan2
- OR10H5 | c.64del p.H22Tfs*4 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as COSV58277901; called by mutect2, pindel, varscan2
- OR10Z1 | c.850dup p.L284Pfs*3 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | catalogued as rs745317170; called by mutect2, pindel, varscan2
- OR1N1 | c.382del p.L128Sfs*7 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as COSV100509697; called by mutect2, pindel, varscan2
- OR2L13 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100813681; called by mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5D14 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1398898438, COSV59456577; called by muse, mutect2, varscan2
- OTOF | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs756388245; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- PAK4 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1052399906; called by muse, mutect2
- PALLD | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768538351, COSV54992233; called by muse, mutect2, varscan2
- PAQR9 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100503817; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as CM011452; called by mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PCDH10 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367823724; called by muse, mutect2, varscan2
- PCDHA6 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65347006; called by muse, mutect2, varscan2
- PCDHA7 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV65344808; called by muse, mutect2, varscan2
- PCDHAC2 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1554229541; called by muse, mutect2, varscan2
- PCDHB14 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as rs782632036, COSV53391335, COSV53391551; called by muse, mutect2, varscan2
- PCDHB8 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1250908322; called by muse, mutect2, varscan2
- PCDHGB1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1207518184, COSV54049007; called by muse, mutect2, varscan2
- PCDHGB3 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs757866605; called by muse, mutect2, varscan2
- PCDHGC3 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.239); catalogued as rs1213404395, COSV52768677; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PCYOX1L | c.1197del p.K400Sfs*8 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as rs750898383, COSV51002139; called by mutect2, pindel, varscan2
- PCYT1A | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492517; called by muse, mutect2, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | catalogued as rs768249210; called by mutect2, varscan2
- PDCD11 | c.4471G>A p.G1491S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs542819088; called by muse, mutect2, varscan2
- PDE5A | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1560639322; called by muse, mutect2
- PDIA4 | c.1444G>A p.E482K (on ENST00000286091 / NM_001371244.1; = p.E481K on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs369276090; called by muse, mutect2, varscan2
- PDLIM7 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs748660598; called by muse, mutect2, varscan2
- PEAR1 | c.2865del p.R956Gfs*30 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs774951036; called by mutect2, varscan2
- PELO | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99252255; called by muse, mutect2, varscan2
- PELP1 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.792); catalogued as rs765738529; called by mutect2, varscan2
- PEPD | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs544921062; called by muse, mutect2, varscan2
- PER3 | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as rs1232390742; called by muse, mutect2, varscan2
- PEX5L | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99830097; called by muse, mutect2, varscan2
- PFKM | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888929546, COSV56659333; called by muse, mutect2, varscan2
- PGBD1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs199718652; called by muse, mutect2, varscan2
- PGLYRP3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51953384; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs769717544; called by mutect2, varscan2
- PIANP | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs181795908, COSV57708603; called by muse, mutect2, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs749506841; called by mutect2, varscan2
- PKD1 | c.12811C>T p.P4271S (on ENST00000262304 / NM_001009944.3; = p.P4270S on NM_000296.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as rs1362627073; called by muse, mutect2
- PKDREJ | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs765492437; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs745860467; called by mutect2, varscan2
- PLAGL2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs746032412, COSV55789566; called by muse, mutect2, varscan2
- PLB1 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs145179606; called by muse, mutect2, varscan2
- PLCB2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs761699247, COSV53031981; called by muse, mutect2, varscan2
- PLEKHA2 | c.489C>T p.N163= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as rs533387323; called by muse, mutect2, varscan2
- PLEKHA4 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs370885533; called by muse, mutect2, varscan2
- PLEKHH3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV52219879; called by muse, mutect2, varscan2
- PLK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621195; called by muse, mutect2, varscan2
- PLXNB3 | c.5441G>A p.R1814Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369580403; called by muse, mutect2, varscan2
- PNMA8A | c.399del p.T134Pfs*57 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1423207473; called by mutect2, pindel, varscan2
- POLE | c.2449G>T p.G817C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267926; called by muse, mutect2, varscan2
- POLR3A | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1167639587, COSV64931950; called by muse, mutect2, varscan2
- POLR3A | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs779250600, COSV64931810; called by muse, mutect2, varscan2
- POLR3D | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1042531655; called by muse, mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- PPM1H | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs760993330, COSV104391347; called by muse, mutect2, varscan2
- PPOX | c.441_442del p.H147Qfs*10 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1432873151; called by pindel, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP1R36 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as rs78726030, COSV100073058; called by muse, mutect2, varscan2
- PPP1R9A | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56884553; called by mutect2, varscan2
- PRDM10 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772111070, COSV62603931; called by muse, mutect2, varscan2
- PRDM4 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747069656, COSV57305387; called by muse, mutect2
- PRRC2C | c.6266G>A p.R2089Q (on ENST00000367742; = p.R2087Q on NM_015172.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1193933979; called by muse, mutect2, varscan2
- PSEN2 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs144277432, CM045430; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV101122574; called by mutect2, varscan2
- PSMF1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55675330; called by muse, mutect2, varscan2
- PTPRM | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as rs1007495793, COSV59873148; called by muse, mutect2, varscan2
- PTPRM | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764281560, COSV100160230; called by muse, mutect2, varscan2
- PXDN | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as rs375938992; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB11FIP2 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012251684; called by muse, mutect2
- RAD21 | c.1579_1581del p.K527del | In Frame Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs1365277271; called by mutect2, pindel, varscan2
- RAD54L2 | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.565); catalogued as rs143819415; called by muse, mutect2, varscan2
- RAPH1 | c.1726G>A p.V576I (on ENST00000319170 / NM_213589.3; = p.V628I on NM_203365.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778234640; called by muse, mutect2, varscan2
- RASA1 | c.1793T>C p.L598S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57195061; called by muse, mutect2, varscan2
- RASA1 | c.2543T>C p.L848P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57200535; called by muse, varscan2
- RASEF | c.669C>T p.D223= | Splice Region (SNP) | VAF 16/59 reads (27%) | catalogued as rs775461169; called by muse, mutect2, varscan2
- RASGRP1 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs1045163521, COSV60367939; called by muse, mutect2, varscan2
- RASGRP3 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200007507, COSV67822907; called by mutect2, varscan2
- RAVER2 | c.2060del p.K687Rfs*15 (on ENST00000294428 / NM_001366165.1; = p.K674Rfs*15 on NM_018211.4) | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as COSV53805154; called by mutect2, pindel, varscan2
- RBBP4 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs867168487; called by muse, mutect2, varscan2
- RBBP6 | c.4834G>A p.V1612I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1225410576; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs762006287; called by mutect2, varscan2
- RCHY1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs1180170921, COSV61009811; called by muse, mutect2, varscan2
- RECK | c.1326del p.K442Nfs*27 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs71508012; called by mutect2, pindel, varscan2
- RELB | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1259719710, COSV55508351; called by muse, mutect2, varscan2
- RELN | c.9035C>T p.A3012V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1256148536; called by muse, mutect2, varscan2
- RFX5 | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as rs972632936, COSV51838069; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs751982308; called by mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIMBP2 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1233215320, COSV55469947; called by muse, mutect2, varscan2
- RNF144A | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57983357; called by muse, mutect2, varscan2
- RNF20 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs779556011; called by muse, mutect2, varscan2
- RNF220 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs772618757, COSV62406450, COSV62409791; called by muse, mutect2, varscan2
- RNF44 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as rs750157294; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA4 | c.76_78del p.E26del | In Frame Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs1565066456; called by pindel, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs747510098; called by mutect2, varscan2
- RTN4 | c.3323G>A p.R1108H (on ENST00000337526 / NM_020532.5; = p.R115H on NM_007008.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs888288659, COSV58271916; called by muse, mutect2, varscan2
- RYR1 | c.12184G>A p.D4062N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs761408598, COSV62087139; called by muse, mutect2, varscan2
- S1PR5 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.59); catalogued as rs777770115; called by muse, mutect2, varscan2
- SCAMP4 | c.393G>A p.A131= | Splice Region (SNP) | VAF 15/62 reads (24%) | catalogued as rs201790720; called by muse, mutect2, varscan2
- SCAP | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55563020; called by muse, mutect2, varscan2
- SCFD1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1286869412; called by muse, mutect2, varscan2
- SCLY | c.835C>T p.R279* (on ENST00000651534; = p.R271* on NM_016510.7) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs367978630; called by mutect2, varscan2
- SCN2A | c.1386G>A p.A462= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as rs145912536; ClinVar: likely benign; called by muse, varscan2
- SCN3A | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376645098, COSV51805409; called by muse, mutect2, varscan2
- SCN5A | c.5960A>G p.N1987S (on ENST00000333535 / NM_198056.3; = p.N1986S on NM_000335.5) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as COSV61122815; called by muse, mutect2, varscan2
- SCNN1A | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.825); catalogued as rs201693951, COSV57437341; called by mutect2, varscan2
- SCUBE3 | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464548360, COSV51460031; called by muse, mutect2, varscan2
- SDC3 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549486633, COSV59578348; called by muse, mutect2
- SELENON | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs775897489, COSV100823421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4B | c.2467del p.R823Gfs*18 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs1471022073; called by pindel, varscan2
- SETD1A | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs771239116, COSV52686025; called by muse, mutect2, varscan2
- SETD6 | c.535_537del p.K179del (on ENST00000219315 / NM_001160305.4; = p.K155del on NM_024860.3) | In Frame Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs1179845666; called by mutect2, pindel, varscan2
- SETDB1 | c.3669+1G>A p.X1223_splice | Splice Site (SNP) | VAF 8/43 reads (19%) | catalogued as rs111660370; called by muse, mutect2, varscan2
- SEZ6L2 | c.727dup p.R243Pfs*75 (on ENST00000308713 / NM_001114099.3; = p.R173Pfs*75 on NM_012410.4) | Frame Shift Ins (INS) | VAF 27/134 reads (20%) | catalogued as rs766468782; called by mutect2, pindel, varscan2
- SH3BP4 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs769192564; called by muse, mutect2, varscan2
- SHISAL1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1246516458, COSV101152160; called by muse, mutect2, varscan2
- SHTN1 | c.1607dup p.T537Nfs*3 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | catalogued as rs770680326; called by mutect2, varscan2
- SIDT1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs766321611; called by muse, mutect2, varscan2
- SIPA1L2 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs770215522, COSV53387607; called by muse, mutect2, varscan2
- SLC16A14 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs746614915; called by muse, mutect2, varscan2
- SLC1A6 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1364120285, COSV55667975, COSV55672668; called by muse, mutect2, varscan2
- SLC25A16 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245395748, COSV56264731; called by muse, mutect2, varscan2
- SLC2A12 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV51599755; called by muse, mutect2, varscan2
- SLC2A9 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs780985240; called by muse, mutect2, varscan2
- SLC30A10 | c.1251del p.A419Hfs*19 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs757727959; called by mutect2, pindel, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC43A1 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1230300975, COSV99560914; called by muse, mutect2, varscan2
- SLC4A7 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV55400593; called by muse, mutect2
- SLC4A8 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs376308798; called by mutect2, varscan2
- SLC5A7 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs751468033, COSV50895986; called by muse, mutect2, varscan2
- SLC6A14 | c.126del p.K42Nfs*8 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as COSV100903217; called by mutect2, pindel, varscan2
- SLC9A1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs776300965; called by muse, mutect2, varscan2
- SLC9A9 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as rs375659735, CM088159; called by muse, mutect2, varscan2
- SLIT2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1210279978, COSV56588449, COSV56598602; called by muse, mutect2, varscan2
- SLITRK2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100157961; called by mutect2, varscan2
- SMARCD2 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs969122171; called by muse, mutect2, varscan2
- SMC6 | c.1180del p.S394Vfs*20 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs761535042; called by mutect2, pindel, varscan2
- SMUG1 | c.434del p.F145Sfs*84 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV54538912; called by mutect2, pindel, varscan2
- SNRNP27 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1055209804, COSV54912016, COSV99732083; called by muse, mutect2, varscan2
- SNUPN | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs377184433; called by muse, mutect2, varscan2
- SOBP | c.2234C>A p.P745Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs757634793, COSV58000409; called by muse, mutect2, varscan2
- SORL1 | c.5627C>T p.T1876M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs149445303; called by muse, mutect2, varscan2
- SOWAHD | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59649383; called by muse, mutect2, varscan2
- SOX17 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV52027981; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs746109620; called by mutect2, varscan2
- SPAG16 | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1416634254; called by muse, mutect2, varscan2
- SPNS3 | c.1382dup p.G462Rfs*29 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | catalogued as rs756918252; called by pindel, varscan2
- SRRM3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs527778424; called by muse, mutect2, varscan2
- SSH2 | c.3700C>T p.R1234C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs774619298, COSV52165915; called by muse, mutect2, varscan2
- ST6GAL2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | PolyPhen probably damaging (0.936); catalogued as rs141942088; called by muse, mutect2, varscan2
- STAT1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1473494120, COSV63115274; called by muse, mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 13/115 reads (11%) | catalogued as rs746501298; called by mutect2, varscan2
- STH | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV52237096; called by muse, mutect2
- SUPT6H | c.4972C>T p.R1658W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs772337051; called by muse, mutect2, varscan2
- SUSD3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100968916, COSV64937021; called by muse, mutect2, varscan2
- SYDE1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs1204867970; called by muse, mutect2, varscan2
- SYNPO2L | c.2728del p.R910Efs*44 (on ENST00000394810 / NM_001114133.3; = p.R686Efs*44 on NM_024875.5) | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs764821235; called by mutect2, pindel, varscan2
- SZT2 | c.6948del p.S2317Pfs*17 (on ENST00000634258 / NM_001365999.1; = p.S2260Pfs*17 on NM_015284.4) | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs753888420; called by mutect2, pindel
- TBC1D21 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383194017, COSV55995416; called by muse, mutect2, varscan2
- TBC1D32 | c.2140T>C p.Y714H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs1277900319; called by muse, mutect2, varscan2
- TBC1D8 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs533724239; called by muse, mutect2, varscan2
- TCF12 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754118933, COSV51003848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRD6 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs975491395, COSV60177599; called by muse, mutect2, varscan2
- TGM1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.303); catalogued as rs139837741, COSV52865015; called by muse, mutect2, varscan2
- TH | c.491G>A p.R164H (on ENST00000381178 / NM_199292.3; = p.R133H on NM_000360.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs376881948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIE1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs759222423, COSV100992120; called by muse, varscan2
- TLCD1 | c.413del p.G138Vfs*3 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as COSV99261755; called by mutect2, pindel, varscan2
- TLE2 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53581641; called by muse, mutect2
- TLX3 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV51540640; called by muse, varscan2
- TMCC2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs758271157; called by muse, mutect2, varscan2
- TMEFF2 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559162270; called by mutect2, varscan2
- TMEM132B | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554924533, COSV54756271; called by muse, mutect2, varscan2
- TMEM200B | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1362692869, COSV58040457; called by muse, mutect2, varscan2
- TMEM229B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1383940203, COSV62538960; called by muse, mutect2, varscan2
- TMTC1 | c.2026G>A p.A676T (on ENST00000539277 / NM_001193451.2; = p.A568T on NM_175861.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs771180850; called by muse, mutect2, varscan2
- TNFRSF8 | c.1310-1G>T p.X437_splice | Splice Site (SNP) | VAF 18/138 reads (13%) | catalogued as COSV55798413; called by muse, mutect2
- TNRC6B | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1302330477; called by muse, mutect2, varscan2
- TNXB | c.12856G>A p.G4286S (on ENST00000647633; = p.G4039S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.026); catalogued as rs762169843; called by muse, mutect2, varscan2
- TOPBP1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1295004358; called by muse, mutect2, varscan2
- TPSD1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.689); catalogued as rs144003164; called by muse, mutect2, varscan2
- TRAF3IP1 | c.768dup p.K257Efs*44 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs768602332; called by mutect2, varscan2
- TRAPPC10 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs746025431; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs770561785; called by mutect2, varscan2
- TRIM4 | c.1450del p.W484Gfs*2 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1254691563; ClinVar: not provided; called by mutect2, pindel
- TRIO | c.3028G>A p.V1010I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1050603011; called by muse, mutect2, varscan2
- TRPC3 | c.367G>A p.G123S (on ENST00000379645 / NM_001366479.2; = p.G50S on NM_003305.2) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374492, COSV99313290; called by muse, mutect2, varscan2
- TRPM6 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs747190057; called by muse, mutect2, varscan2
- TRRAP | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs782009444, COSV62843436; called by muse, mutect2, varscan2
- TSPAN32 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs756322762; called by mutect2, varscan2
- TTBK1 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV52498560; called by muse, mutect2, varscan2
- TTC37 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1033302823, COSV62453770; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.30111del p.E10038Kfs*39 (on ENST00000591111; = p.E9111Kfs*39 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs1560454926; called by mutect2, pindel, varscan2
- TUT7 | c.2842del p.Y948Mfs*16 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs751076382; called by mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs760251146; called by mutect2, varscan2
- UBOX5 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs139376372; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs767420916; called by mutect2, varscan2
- USP22 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs911964526; called by muse, mutect2, varscan2
- USP24 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs1400885299; called by muse, mutect2, varscan2
- VARS1 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368988920; called by muse, mutect2
- VAX1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53329064, COSV53330049; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1158703313; called by pindel, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 28/101 reads (28%) | catalogued as rs773064295, COSV51967888; called by mutect2, varscan2
- WDPCP | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs761751600, COSV55418868; called by muse, mutect2, varscan2
- WIPI1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs1568626256; called by muse, mutect2, varscan2
- WNK2 | c.6530C>T p.A2177V (on ENST00000297954 / NM_001282394.1; = p.A2140V on NM_006648.3) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as rs1193417697, COSV99942814; called by muse, mutect2, varscan2
- WNK2 | c.6704C>T p.P2235L (on ENST00000297954 / NM_001282394.1; = p.P2198L on NM_006648.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1247542757, COSV52956703; called by muse, mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV53295493; called by mutect2, pindel, varscan2
- WWC3 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as rs372649547, COSV66501536; called by muse, varscan2
- XKR4 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs748566342, COSV59308517; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as rs762052135; called by mutect2, varscan2
- YES1 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs765723765; called by muse, mutect2, varscan2
- YY1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51764380; called by muse, mutect2
- ZACN | c.756del p.L253Cfs*10 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs746294699; called by mutect2, pindel, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs751577786; called by mutect2, varscan2
- ZCCHC4 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100255301, COSV57180905; called by muse, mutect2, varscan2
- ZCRB1 | c.419dup p.K141Efs*4 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs750821771; called by mutect2, varscan2
- ZCWPW1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61249722; called by muse, mutect2, varscan2
- ZDHHC18 | c.786C>T p.R262= | Splice Region (SNP) | VAF 18/41 reads (44%) | catalogued as rs753598475, COSV65145177, COSV65145268; called by muse, mutect2, varscan2
- ZFAND4 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs573366778; called by muse, mutect2, varscan2
- ZFHX4 | c.1020del p.K340Nfs*15 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs774274741; called by mutect2, varscan2
- ZHX2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs373708916; called by muse, mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs751589999; called by mutect2, pindel, varscan2
- ZNF208 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV68101616, COSV68103083; called by muse, mutect2, varscan2
- ZNF257 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs189763118, COSV101448071, COSV71307260; called by muse, mutect2, varscan2
- ZNF292 | c.3470dup p.L1157Ffs*64 | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | catalogued as rs1306238628; called by mutect2, pindel, varscan2
- ZNF326 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768705120, COSV61036011; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF407 | c.5014G>A p.A1672T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369381731, COSV55271233; called by muse, mutect2, varscan2
- ZNF416 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764468301; called by muse, mutect2, varscan2
- ZNF467 | c.1475G>A p.C492Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766912635; called by mutect2, varscan2
- ZNF485 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.6); catalogued as rs369821326; called by mutect2, varscan2
- ZNF500 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs748564401; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF518B | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs185473572, COSV58721412; called by muse, mutect2, varscan2
- ZNF530 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs746432145, COSV60532285; called by muse, mutect2, varscan2
- ZNF646 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs140829625; called by muse, mutect2, varscan2
- ZNF648 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV60570812; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as rs760397907; called by pindel, varscan2
- ZNF695 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs757231466, COSV60587099; called by muse, mutect2, varscan2
- ZNF705A | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100828306; called by muse, mutect2
- ZNF746 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61408235; called by muse, mutect2, varscan2
- ZNF76 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762796432; called by muse, mutect2, varscan2
- ZNF79 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs191043127; called by muse, mutect2, varscan2
- ZRANB3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1268342214, COSV51506627; called by muse, mutect2, varscan2
- ZXDC | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750799915; called by muse, mutect2, varscan2
- AARS2 | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCA10 | c.3159del p.F1053Lfs*4 | Frame Shift Del (DEL) | VAF 38/75 reads (51%) | called by mutect2, pindel, varscan2
- ABCA13 | c.10682G>A p.S3561N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ABCF1 | c.118del p.T40Rfs*8 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- ACAA2 | c.58dup p.Y20Lfs*12 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- ACADSB | c.1143_1145del p.T382del | In Frame Del (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- ACSBG2 | c.230del p.K77Sfs*5 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- ACTN3 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTN4 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ACTRT2 | c.911del p.G304Afs*48 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ADAMTS9 | c.4043C>A p.S1348Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ADCK5 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ADGRV1 | c.16197G>A p.R5399= | Splice Region (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- ADTRP | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- AFAP1L1 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AIFM2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- AKAP13 | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AKAP13 | c.7325C>T p.T2442I (on ENST00000394518 / NM_007200.5; = p.T2446I on NM_006738.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- AKAP13 | c.7669G>A p.A2557T (on ENST00000394518 / NM_007200.5; = p.A2561T on NM_006738.6) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- AKIRIN2 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AL121899.2 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ALCAM | c.458del p.K153Sfs*34 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- ALG11 | c.153dup p.L52Ifs*5 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- ALK | c.3500A>C p.E1167A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANGPTL2 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, varscan2
- ANGPTL4 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ANKRD17 | c.5651C>T p.A1884V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANLN | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANO8 | c.438_440del p.E146del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- ANXA11 | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- APOA1 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ARAP2 | c.1317del p.A440Pfs*2 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP11B | c.375del p.F125Lfs*18 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- ARHGAP17 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP21 | c.2990A>T p.D997V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP28 | c.982G>T p.G328C (on ENST00000383472 / NM_001366230.1; = p.G169C on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF12 | c.2510A>T p.D837V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ARHGEF26 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID1B | c.5203G>A p.E1735K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARID4B | c.3001dup p.T1001Nfs*6 | Frame Shift Ins (INS) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- ASPDH | c.467G>A p.G156D (on ENST00000389208 / NM_001114598.2; = p.G51D on NM_001024656.3) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATL1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ATP13A2 | c.2574G>T p.Q858H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP13A3 | c.821T>A p.V274D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ATP1A1 | c.74del p.K25Rfs*11 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP4A | c.2045dup p.D683Gfs*50 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- ATP9A | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ATRN | c.693del p.F231Lfs*8 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- ATRN | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- AURKAIP1 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AUTS2 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- AXIN1 | c.1326del p.A443Lfs*37 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- AZI2 | c.48del p.A17Pfs*7 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- B4GALNT2 | c.547del p.R183Afs*22 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- BRD8 | c.2428C>T p.Q810* (on ENST00000254900 / NM_139199.2; = p.Q883* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- BTAF1 | c.3437del p.L1146Wfs*27 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- BUD13 | c.989del p.K330Sfs*103 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, varscan2
- C1QTNF9 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf16 | c.5305C>T p.P1769S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CAB39L | c.10del p.M4Cfs*15 | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | called by mutect2, pindel, varscan2
- CABIN1 | c.737del p.K246Rfs*5 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- CACNA1H | c.2297G>A p.R766K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.3724G>A p.V1242M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CACNA2D3 | c.1254dup p.T419Yfs*8 | Frame Shift Ins (INS) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CACNG6 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CAD | c.2750T>C p.L917P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMKK2 | c.1493A>G p.N498S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by mutect2, varscan2
- CAMKV | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CAMSAP2 | c.94del p.I32Sfs*72 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.1147dup p.E383Gfs*15 (on ENST00000236925 / NM_001297707.2; = p.E372Gfs*15 on NM_203459.3) | Frame Shift Ins (INS) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.1109dup p.D371Gfs*37 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- CAPN1 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
996 further variants in this file (576 protein-altering or splice-affecting, 374 silent, 46 other) are not listed here.
